Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB2L, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB2L-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

Fibromyx sarcoma 8811/3
Site: thigh, NOS C49.2
hw, 1/23/15

SURGICAL PATHOLOGY REPORT

Clinical Diagnosis & History:

Status post attempted resection of right thigh high grade myxofibrosarcoma with multiple positive margins.

Specimens Submitted:

1: SP: Radical resection right upper thigh

DIAGNOSIS:

1. SOFT TISSUE, RIGHT UPPER THIGH MASS, RADICAL RESECTION:
- EXUBERANT GRANULATION TISSUE, BIOPSY CAVITY AND FOREIGN BODY GIANT CELL REACTION.
- NO RESIDUAL SARCOMA IS SEEN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) Received fresh, labeled as "radical resection right upper thigh sarcoma, short stitch superior margin long stitch posterior margin" consists of a tan skin ellipse (17.5 x 5.5 cm) with a 7.5 cm linear scar, with 18 x 12 x 4.5 cm soft tissue attached underneath. The specimen is oriented by sutures. External surface is inked with black for posterior, green for lateral, blue for medial, yellow for superior, and red for inferior. Sections reveal a 6.5 x 3.5 x 1.7 cm cystic cavity with a 0.2 cm fibrous wall, 6.5 cm from superior, 6 cm from inferior, 2 cm from posterior, 3 cm from lateral and 0.8 cm from medial margin. Definite mass lesion is not identified. Photograph is taken.

Sections.

Sm superior margin
Pm-posterior margin
mm-medial margin

** Continued on next page **

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

lm-lateral margin

im-inferior margin

c cystic cavity, entirely submitted.

u- normal skin and uninvolved area

Page 2 of 2

Summary of Sections:

Part 1: SP: Radical resection right upper thigh

Block	Sect.	Site	PCs
19		c	24
1		im	1
1		lm	1
1		mm	1
1		pm	1
1		sm	1
1		u	1

** End of Report **

New / updated path report. Original
path signed 1/21/14.

Criteria	1/23/15	Yes	No

Source: NCI Genomic Data Commons file 4080dc54-a469-4f22-84bd-035349d6b64c (TCGA-DX-AB2L.F4EB8D3E-97C2-447F-A361-27A318CAFB16.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).